Somatic mutation profile of tumor specimen BLGSP-71-08-00508-01B (aliquot BLGSP-71-08-00508-01B-01D-A690-33) from CGCI case BLGSP-71-08-00508, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male.
Specimen BLGSP-71-08-00508-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ee5a021-387d-473a-9737-fe7082bc728b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00508-10A (Blood Derived Normal), aliquot BLGSP-71-08-00508-10A-01D-A690-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab65227d-ae8b-4f7b-bccd-8deabb3fc12d

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 342/384 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, varscan2
- RHOA | c.101A>T p.Y34F | Missense Mutation (SNP) | VAF 225/546 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV69041520, COSV69042084; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 59/180 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXO11 | c.2084-2A>G p.X695_splice (on ENST00000403359 / NM_001190274.2; = p.X611_splice on NM_025133.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 113/352 reads (32%) | catalogued as COSV52276686; called by muse, mutect2, varscan2
- GPR32 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs746445364, COSV54513842, COSV54514973; called by muse, mutect2, varscan2
- ARID1A | c.6420dup p.F2141Lfs*9 | Frame Shift Ins (INS) | VAF 99/283 reads (35%) | called by mutect2, pindel, varscan2
- MYC | c.-54G>A | 5'UTR (SNP) | VAF 85/209 reads (41%) | catalogued as rs780034860, COSV52374605, COSV52375385; called by muse, mutect2, varscan2
